Somatic mutation profile of tumor specimen TCGA-EA-A5ZF-01A (aliquot TCGA-EA-A5ZF-01A-11D-A28B-09) from TCGA case TCGA-EA-A5ZF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 56.1 years (20,506 days).
Specimen TCGA-EA-A5ZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 512c109d-f87b-422c-8730-b5aac0ed575d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A5ZF-10A (Blood Derived Normal), aliquot TCGA-EA-A5ZF-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4a34231-c54e-429c-a259-8c5fa29d2cb4

The open-access MAF lists 85 somatic variants for this specimen: 56 protein-altering or splice-affecting, 29 silent.
By variant classification: Missense Mutation 44, Silent 29, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, In Frame Ins 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.5885G>A p.R1962H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV54031566; called by muse, mutect2, varscan2
- ACHE | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs535618245, COSV53820884; called by muse, mutect2, varscan2
- ALOX5 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.187); catalogued as COSV65554012; called by muse, mutect2, varscan2
- ARHGAP17 | c.2024C>T p.P675L (on ENST00000289968 / NM_001006634.3; = p.P597L on NM_018054.6) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); catalogued as COSV51511262; called by muse, mutect2, varscan2
- BRSK2 | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57547981; called by muse, mutect2, varscan2
- CAPN3 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142004418, CM040390; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- CNGA4 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs371882863; called by muse, mutect2, varscan2
- CPSF1 | c.3820C>A p.R1274S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.097); catalogued as rs782448023, COSV100450294, COSV58233689; called by muse, mutect2
- CPT1B | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753278512, COSV56418610; called by muse, mutect2, varscan2
- CXorf66 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 29/149 reads (19%) | catalogued as COSV65169696; called by muse, mutect2, varscan2
- DCC | c.3764C>T p.T1255M | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs775848107, COSV101473552, COSV71434183; called by muse, mutect2, varscan2
- DDHD2 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as COSV104432464, COSV68158608; called by muse, mutect2, varscan2
- DGKI | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs750429253, COSV55959948; called by muse, mutect2, varscan2
- DMD | c.8262C>G p.N2754K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV58943818; called by mutect2, varscan2
- GAB2 | c.1505C>T p.P502L (on ENST00000361507 / NM_080491.3; = p.P464L on NM_012296.3) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs778004853, COSV60870442; called by muse, mutect2, varscan2
- GAPDHS | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs768556924, COSV55881256, COSV99722451; called by muse, mutect2, varscan2
- H2AW | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100797259; called by muse, mutect2
- HRC | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53255510; called by muse, mutect2, varscan2
- IGF2R | c.4471G>A p.V1491M | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs761398978, COSV63631231; called by muse, mutect2, varscan2
- INPP5D | c.1283C>G p.S428C (on ENST00000445964 / NM_001017915.3; = p.S427C on NM_005541.5) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV64039711; called by muse, mutect2, varscan2
- KIAA1109 | c.10270A>T p.T3424S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52688598; called by muse, mutect2, varscan2
- LIN9 | c.1707C>G p.I569M (on ENST00000366808 / NM_001270410.2; = p.I514M on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs754175670, COSV60246681; called by muse, mutect2, varscan2
- LTF | c.286G>T p.V96L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV51611308; called by muse, mutect2, varscan2
- MTF1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65990271; called by muse, mutect2
- NAGS | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV52814050; called by muse, mutect2, varscan2
- OR6Q1 | c.640T>G p.S214A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV56934345; called by muse, mutect2
- PALLD | c.2376G>T p.M792I (on ENST00000505667 / NM_001166108.2; = p.M775I on NM_016081.4) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54991963; called by muse, mutect2, varscan2
- PHACTR1 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV60678702; called by muse, mutect2, varscan2
- PHKA2 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV101177512, COSV66055770; called by muse, mutect2
- PIK3AP1 | c.2417G>C p.*806Sext*26 | Nonstop Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV59530831, COSV59536235; called by muse, mutect2, varscan2
- PIK3R4 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs965941646, COSV63243481; called by muse, mutect2, varscan2
- PNMA5 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV62626139; called by muse, mutect2, varscan2
- PPP4R3B | c.1565-2A>G p.X522_splice (on ENST00000616407 / NM_001122964.3; = p.X490_splice on NM_020463.4) | Splice Site (SNP) | VAF 26/50 reads (52%) | catalogued as rs762049366, COSV55408371; called by muse, mutect2, varscan2
- RBBP8 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV59095425; called by muse, mutect2, varscan2
- RBFOX1 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs1284886681, COSV60975615; called by muse, mutect2, varscan2
- RELN | c.3333+1G>C p.X1111_splice | Splice Site (SNP) | VAF 17/64 reads (27%) | catalogued as COSV59028797; called by muse, mutect2, varscan2
- SALL4 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1415936268, COSV53851020; called by muse, mutect2, varscan2
- SCN2B | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs753389706, COSV54050745, COSV99635611; ClinVar: uncertain significance; called by muse, varscan2
- SERPINA4 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs1278033042, COSV54069426; called by muse, mutect2, varscan2
- SH3TC1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.131); catalogued as rs929982389, COSV99794603; called by muse, mutect2
- SLC24A1 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373174484; called by muse, mutect2, varscan2
- SLC7A4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs9613553, COSV60385735; called by muse, mutect2, varscan2
- SYNE1 | c.16409A>G p.D5470G (on ENST00000367255 / NM_182961.4; = p.D5399G on NM_033071.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs747824937, COSV55075851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM3 | c.6847G>T p.A2283S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV69316758; called by muse, mutect2, varscan2
- TICAM1 | c.2008C>A p.P670T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs757840131, COSV50238629; called by muse, mutect2, varscan2
- TP53I11 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57533981; called by muse, mutect2, varscan2
- UBXN4 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV55637382; called by muse, mutect2
- WNK2 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745435224, COSV99941495; called by muse, mutect2, varscan2
- ZNF681 | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs1390584386, COSV68075403; called by muse, mutect2, varscan2
- ZNF880 | c.695G>T p.R232I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as rs528402600, COSV69906782; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7811_7819dup p.G2604_A2606dup | In Frame Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, varscan2
- CWC25 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- IL12B | c.309_311del p.L104del | In Frame Del (DEL) | VAF 11/41 reads (27%) | called by pindel, varscan2
- NGDN | c.906_907del p.Q303Efs*30 (on ENST00000408901 / NM_001042635.2; = p.Q303Efs*88 on NM_015514.2) | Frame Shift Del (DEL) | VAF 20/41 reads (49%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.8641del p.L2881Ffs*16 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | called by mutect2, pindel, varscan2
- TNKS1BP1 | c.3393_3394del p.R1131Sfs*7 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by pindel, varscan2
- ADAMTSL3 | c.3747G>A p.Q1249= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV54464475, COSV54465122; called by muse, mutect2, varscan2
- AGXT2 | c.51C>T p.S17= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs144847973; called by muse, mutect2, varscan2
- ARHGAP9 | c.1857G>A p.L619= (on ENST00000393797 / NM_001319850.2; = p.L600= on NM_032496.4) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV57366033; called by muse, mutect2, varscan2
- CBR1 | c.378C>G p.L126= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV51739956; called by muse, mutect2, varscan2
- CD19 | c.1536C>G p.P512= (on ENST00000324662 / NM_001178098.2; = p.P511= on NM_001770.6) | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV61189460; called by muse, mutect2, varscan2
- COQ7 | c.81A>G p.G27= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV58982425; called by muse, mutect2, varscan2
- CUL4B | c.1641A>C p.A547= | Silent (SNP) | VAF 20/147 reads (14%) | catalogued as COSV100340038, COSV60690497; called by muse, mutect2, varscan2
- DPT | c.330G>T p.G110= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV63190097, COSV63190817; called by muse, mutect2, varscan2
- FOXP3 | c.606C>T p.P202= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs370196156, COSV66051911; called by muse, mutect2, varscan2
- GPR45 | c.435G>A p.P145= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs753817223, COSV51525829; called by muse, mutect2, varscan2
- GPR50 | c.111C>A p.I37= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as rs1013442300, COSV99505846; called by muse, mutect2
- KRT72 | c.1038C>T p.L346= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs908684975, COSV53376389; called by muse, mutect2, varscan2
- MAP3K7 | c.1233C>T p.G411= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV65225686; called by muse, mutect2, varscan2
- NPAP1 | c.1833G>A p.Q611= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as COSV61509056; called by muse, mutect2, varscan2
- OPN5 | c.96G>A p.A32= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs375496580, COSV55247204; called by muse, mutect2, varscan2
- OR13H1 | c.450G>A p.G150= | Silent (SNP) | VAF 79/133 reads (59%) | catalogued as rs1218240968, COSV58548350; called by muse, mutect2
- OR8D4 | c.711G>A p.A237= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs568693746, COSV58431321; called by muse, mutect2
- PPP2R3B | c.1314C>T p.L438= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV66814275; called by muse, mutect2, varscan2
- PXYLP1 | c.1278C>T p.V426= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as rs751433640, COSV53889586, COSV53889652; called by muse, mutect2, varscan2
- RCC1L | c.1263C>T p.N421= | Silent (SNP) | VAF 65/191 reads (34%) | catalogued as COSV57320760; called by muse, mutect2, varscan2
- SLC6A8 | c.204C>T p.F68= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs782128137, COSV53472464; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLITRK2 | c.1503G>A p.L501= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV59424195, COSV59428066; called by muse, mutect2, varscan2
- SPATA32 | c.408C>T p.F136= | Silent (SNP) | VAF 32/48 reads (67%) | catalogued as COSV59303160, COSV59304029; called by muse, mutect2
- SPDYE3 | c.72G>A p.Q24= | Silent (SNP) | VAF 8/167 reads (5%) | catalogued as COSV60108156; called by muse, mutect2
- SPIRE1 | c.1668C>T p.L556= (on ENST00000409402 / NM_001128626.2; = p.L542= on NM_020148.3) | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs763662699, COSV100563475; called by muse, mutect2, varscan2
- SYNCRIP | c.1446A>G p.E482= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV100784116; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3555C>G p.L1185= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV51959408, COSV51960851; called by muse, mutect2, varscan2
- ZBTB33 | c.1398G>T p.T466= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV58534883; called by muse, mutect2, varscan2
- ZNF536 | c.3279C>T p.S1093= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs147863190; called by muse, mutect2, varscan2
